Somatic mutation profile of tumor specimen MMRF_2709_1_BM_CD138pos (aliquot MMRF_2709_1_BM_CD138pos_T1_KHS5U_L14444) from MMRF case MMRF_2709, project MMRF-COMMPASS (Multiple Myeloma CoMMpass Study). Sex at birth: female; Vital status: Alive; Primary diagnosis: Multiple myeloma; Tissue or organ of origin: Bone marrow; Age at diagnosis: 47.3 years (17,280 days).
Specimen MMRF_2709_1_BM_CD138pos: Sample type: Primary Blood Derived Cancer - Bone Marrow; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Bone Marrow NOS.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 8fce44dd-0091-4fb5-8ae1-4334b8434ccc.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen MMRF_2709_1_PB_WBC (Blood Derived Normal), aliquot MMRF_2709_1_PB_WBC_C2_KHS5U_L14445; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/fad81b91-4d7b-4812-ba27-acef564750d8

The open-access MAF lists 62 somatic variants for this specimen: 26 protein-altering or splice-affecting, 7 silent, 29 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 23, 3'UTR 14, Intron 10, Silent 7, 5'UTR 3, Splice Site 2, RNA 1, Frame Shift Del 1, 5'Flank 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- ARFGEF3 | c.2270G>A p.R757Q | Missense Mutation (SNP) | VAF 68/137 reads (50%) | SIFT tolerated (0.31); PolyPhen benign (0.026); catalogued as rs150705933; called by muse, mutect2, varscan2
- ART3 | c.781+1del | Frame Shift Del (DEL) | VAF 9/60 reads (15%) | catalogued as COSV100587824; called by mutect2, pindel, varscan2
- CCND3 | c.350C>T p.T117M | Missense Mutation (SNP) | VAF 12/185 reads (6%) | SIFT tolerated (0.27); PolyPhen benign (0.022); catalogued as rs1212176998; called by muse, mutect2
- CNDP1 | c.473T>C p.L158P | Missense Mutation (SNP) | VAF 6/121 reads (5%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV62593281; called by muse, mutect2
- CTNNA2 | c.1264C>T p.R422C | Missense Mutation (SNP) | VAF 6/164 reads (4%) | SIFT deleterious (0.02); PolyPhen benign (0.208); catalogued as COSV58154482; called by muse, mutect2
- DNAH1 | c.8047C>T p.R2683W | Missense Mutation (SNP) | VAF 88/179 reads (49%) | SIFT deleterious (0); PolyPhen probably damaging (0.963); catalogued as rs779766452, COSV70228750; called by muse, mutect2, varscan2
- H2AC11 | c.288G>C p.K96N | Missense Mutation (SNP) | VAF 74/171 reads (43%) | SIFT deleterious, low confidence (0.02); PolyPhen possibly damaging (0.588); catalogued as rs146463878; called by muse, mutect2, varscan2
- HMCN1 | c.9292C>T p.R3098W | Missense Mutation (SNP) | VAF 19/145 reads (13%) | SIFT deleterious (0); PolyPhen possibly damaging (0.906); catalogued as rs1002862471, COSV104376436; called by muse, mutect2, varscan2
- IGFBP2 | c.487G>A p.V163M | Missense Mutation (SNP) | VAF 95/257 reads (37%) | SIFT tolerated (0.05); PolyPhen possibly damaging (0.721); catalogued as rs1362913240, COSV52080087; called by muse, mutect2, varscan2
- IGHJ3 | c.5C>T p.A2V | Missense Mutation (SNP) | VAF 30/51 reads (59%) | PolyPhen benign (0); catalogued as rs183030857; called by muse, mutect2, varscan2
- IGHJ4 | c.25A>G p.T9A | Missense Mutation (SNP) | VAF 42/90 reads (47%) | PolyPhen benign (0.143); catalogued as rs371354427; called by muse, varscan2
- PSEN2 | c.50G>A p.R17Q | Missense Mutation (SNP) | VAF 118/320 reads (37%) | SIFT tolerated (0.09); PolyPhen benign (0.251); catalogued as rs964890810; called by muse, mutect2
- RYR1 | c.3043C>T p.R1015C | Missense Mutation (SNP) | VAF 33/124 reads (27%) | SIFT deleterious (0); PolyPhen probably damaging (0.99); catalogued as rs139006437, COSV62099806; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- UBR3 | c.4741G>A p.E1581K | Missense Mutation (SNP) | VAF 58/198 reads (29%) | SIFT tolerated (0.7); PolyPhen benign (0.019); catalogued as rs749222366; called by muse, varscan2
- FBXO3 | c.1240-1G>A p.X414_splice | Splice Site (SNP) | VAF 18/401 reads (4%) | called by muse, mutect2
- IGHV1-69D | c.193G>A p.E65K | Missense Mutation (SNP) | VAF 40/110 reads (36%) | SIFT deleterious (0.04); PolyPhen benign (0.255); called by mutect2, varscan2
- IGLV3-10 | c.88T>G p.S30A | Missense Mutation (SNP) | VAF 32/178 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (0.979); called by muse, mutect2
- KIAA1210 | c.497A>G p.K166R | Missense Mutation (SNP) | VAF 21/60 reads (35%) | SIFT tolerated (0.1); PolyPhen possibly damaging (0.593); called by muse, mutect2, varscan2
- LAMC1 | c.3937G>A p.D1313N | Missense Mutation (SNP) | VAF 70/192 reads (36%) | SIFT tolerated (0.16); PolyPhen possibly damaging (0.494); called by muse, varscan2
- LRRK2 | c.6112T>G p.F2038V | Missense Mutation (SNP) | VAF 36/90 reads (40%) | SIFT deleterious (0); PolyPhen probably damaging (0.965); called by muse, mutect2, varscan2
- MMRN1 | c.1783A>C p.M595L | Missense Mutation (SNP) | VAF 9/75 reads (12%) | SIFT tolerated (0.29); PolyPhen benign (0.003); called by muse, mutect2, varscan2
- SETX | c.1987A>G p.T663A | Missense Mutation (SNP) | VAF 20/119 reads (17%) | SIFT tolerated (0.56); PolyPhen benign (0); called by muse, mutect2, varscan2
- SMPD3 | c.259C>A p.P87T | Missense Mutation (SNP) | VAF 35/137 reads (26%) | SIFT deleterious (0.04); PolyPhen benign (0.024); called by muse, mutect2, varscan2
- TENM3 | c.4892+1G>A p.X1631_splice | Splice Site (SNP) | VAF 31/87 reads (36%) | called by muse, mutect2, varscan2
- TENT5C | c.650G>C p.G217A | Missense Mutation (SNP) | VAF 33/193 reads (17%) | SIFT deleterious (0); PolyPhen benign (0.368); called by muse, varscan2
- TRO | c.3713G>A p.G1238D | Missense Mutation (SNP) | VAF 50/173 reads (29%) | SIFT tolerated, low confidence (0.41); PolyPhen benign (0.386); called by muse, mutect2, varscan2
- LRAT | c.492C>T p.F164= | Silent (SNP) | VAF 10/216 reads (5%) | catalogued as rs915089130, COSV60476975, COSV60477987; called by muse, mutect2
- MPDZ | c.1215C>A p.I405= | Silent (SNP) | VAF 71/123 reads (58%) | catalogued as COSV59934869; called by muse, mutect2, varscan2
- MYO7A | c.114G>T p.V38= | Silent (SNP) | VAF 47/196 reads (24%) | called by muse, mutect2, varscan2
- ROBO4 | c.712C>T p.L238= | Silent (SNP) | VAF 18/66 reads (27%) | called by muse, mutect2, varscan2
- ST13 | c.1032T>C p.N344= | Silent (SNP) | VAF 10/45 reads (22%) | called by muse, mutect2, varscan2
- THEG | c.33C>T p.N11= | Silent (SNP) | VAF 21/84 reads (25%) | called by muse, mutect2, varscan2
- TRPC5 | c.807C>T p.L269= | Silent (SNP) | VAF 43/108 reads (40%) | catalogued as COSV53300570; called by muse, mutect2, varscan2
- ABI3BP | c.1577-7784del | Intron (DEL) | VAF 24/48 reads (50%) | catalogued as rs756307252; called by mutect2, varscan2
- ADSL | c.1010+91C>T | Intron (SNP) | VAF 19/59 reads (32%) | called by muse, mutect2, varscan2
- ALDH4A1 | c.*41+142C>T | Intron (SNP) | VAF 6/106 reads (6%) | catalogued as rs1259592529; called by muse, mutect2
- APP | c.*1110T>A | 3'UTR (SNP) | VAF 11/35 reads (31%) | called by muse, mutect2, varscan2
- ARPP21 | c.-38-773G>T | Intron (SNP) | VAF 16/58 reads (28%) | called by muse, mutect2
- ATP6V1B1 | c.174+4799G>A | Intron (SNP) | VAF 18/56 reads (32%) | catalogued as rs1553417763; called by muse, mutect2
- CCDC62 | c.*342C>T | 3'UTR (SNP) | VAF 13/58 reads (22%) | called by muse, mutect2, varscan2
- CRB1 | c.3879-682C>A | Intron (SNP) | VAF 26/74 reads (35%) | called by muse, mutect2, varscan2
- DENND1B | c.83-20844T>G | Intron (SNP) | VAF 5/22 reads (23%) | called by muse, mutect2, varscan2
- DEPDC1 | c.-46A>C | 5'UTR (SNP) | VAF 36/98 reads (37%) | called by muse, mutect2, varscan2
- FN1 | c.*44G>T | 3'UTR (SNP) | VAF 91/263 reads (35%) | called by muse, mutect2, varscan2
- FUT11 | c.*495C>T | 3'UTR (SNP) | VAF 29/77 reads (38%) | catalogued as COSV59544926; called by muse, mutect2, varscan2
- GPR37L1 | c.*876C>T | 3'UTR (SNP) | VAF 38/105 reads (36%) | called by muse, mutect2
- LTB | c.162+146T>C | Intron (SNP) | VAF 25/58 reads (43%) | catalogued as rs1252271470; called by muse, mutect2, varscan2
- MIR181B1 | n.47C>T | RNA (SNP) | VAF 58/195 reads (30%) | catalogued as rs1323404832; called by muse, mutect2, varscan2
- MPZL1 | c.*1644C>T | 3'UTR (SNP) | VAF 33/94 reads (35%) | catalogued as rs1392323602; called by muse, mutect2, varscan2
- MYRIP | c.*694C>A | 3'UTR (SNP) | VAF 14/218 reads (6%) | called by muse, mutect2
- NRK | c.-135C>T | 5'UTR (SNP) | VAF 78/222 reads (35%) | called by muse, mutect2, varscan2
- PCDH11X | c.*1525T>G | 3'UTR (SNP) | VAF 94/284 reads (33%) | called by muse, varscan2
- QRFPR | c.-52G>A | 5'UTR (SNP) | VAF 9/32 reads (28%) | catalogued as rs1045783552; called by mutect2, varscan2
- RECQL5 | c.*101C>T | 3'UTR (SNP) | VAF 14/66 reads (21%) | called by muse, mutect2, varscan2
- SH2D4B | chr10:80538275 C>T | 5'Flank (SNP) | VAF 29/61 reads (48%) | called by muse, mutect2, varscan2
- SLITRK5 | c.*605A>C | 3'UTR (SNP) | VAF 22/33 reads (67%) | called by muse, mutect2, varscan2
- SNX1 | c.*5724G>A | 3'UTR (SNP) | VAF 6/116 reads (5%) | called by muse, mutect2
- STEAP2 | c.*281G>A | 3'UTR (SNP) | VAF 31/129 reads (24%) | called by muse, mutect2, varscan2
- TENM4 | c.*3495_*3501dup | 3'UTR (INS) | VAF 56/121 reads (46%) | called by mutect2, varscan2
- TNKS2 | c.*1528T>G | 3'UTR (SNP) | VAF 48/154 reads (31%) | called by muse, mutect2, varscan2
- TRMU | c.772+126G>A | Intron (SNP) | VAF 3/33 reads (9%) | called by muse, mutect2
- WDR49 | c.-65-16114G>A | Intron (SNP) | VAF 12/213 reads (6%) | catalogued as rs907179390, COSV57713303; called by muse, mutect2
